Gene-level copy-number profile of tumor specimen TCGA-MB-A8JL-01A from TCGA case TCGA-MB-A8JL, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Leiomyosarcoma, NOS; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of thorax; Age at diagnosis: 53.4 years (19,510 days).
Specimen TCGA-MB-A8JL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5c587667-20f8-4f13-90e3-03cdfcda3ab1.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-MB-A8JL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bf4c0116-af37-4cce-a763-8bbadaaa10f3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 124; copy number 1: 10,142; copy number 2: 46,223; copy number 3: 3,162; copy number 4: 104; copy number 5: 60.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-MB-A8JL-01A-11D-A36I-01): tumor purity 0.86, ploidy 1.92, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 124 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,140,214–21,305,312, 15 genes: IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5.
- chr9:21,440,439–23,438,700, 29 genes (within-gene range 0–2): IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1, LINC01239, AL391117.1, CLIC4P1, AC017067.1.
- chr16:24,610,209–24,827,632, 1 gene (within-gene range 0–1): TNRC6A.
- chr16:24,803,451–25,454,647, 20 genes: AC008731.1, SLC5A11, ARHGAP17, AC133552.1, AC133552.2, LINC02175, SCML2P2, AC133552.4, LCMT1-AS1, AC133552.3, AC133552.5, LCMT1, LCMT1-AS2, RN7SL557P, AQP8, ZKSCAN2, AC008741.1, ZKSCAN2-DT, LINC02191, CYCSP39.
- chr16:87,773,304–88,715,396, 31 genes: AC126696.3, AC126696.1, SLC7A5, MIR6775, AC126696.2, CA5A, AC133539.1, AC127455.1, BANP, AC134312.4, AC134312.3, AC134312.1, AC134312.2, AC134312.5, LINC02182, AC134312.6, AC138512.1, ZNF469, ZFPM1, MIR5189, AC116552.1, ZC3H18, IL17C, CYBA, MVD, SNAI3-AS1, SNAI3, RNF166, AC138028.3, CTU2, AC138028.6.
- chr16:88,716,278–88,741,425, 3 genes: MIR4722, AC138028.4, AC138028.2.
- chr17:30,897,336–31,538,211, 25 genes (within-gene range 0–1): TEFM, AC130324.3, ADAP2, AC138207.1, RN7SL138P, AC138207.5, AC138207.9, RNF135, AC138207.4, DPRXP4, AC138207.7, AC138207.3, AC138207.8, AC138207.6, AC138207.2, MIR4733, NF1, AC079915.1, OMG, EVI2B, AC134669.1, EVI2A, AK4P1, RAB11FIP4, RN7SL79P.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 60 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:30,658,431–31,332,892, 60 genes, copy number 5 (within-gene range 1–5): FBRS, RNU6-416P, AC093249.6, SRCAP, RNU6-1043P, AC106886.5, SNORA30, TMEM265, AC106886.2, PHKG2, CCDC189, RNF40, AC106886.4, ZNF629, Metazoa_SRP, AC106886.1, AC106886.3, BCL7C, MIR762HG, MIR4519, AC135048.2, MIR762, CTF1, CTF2P, FBXL19-AS1, FBXL19, AC135048.1, ORAI3, AC135048.3, SETD1A, AC135048.4, HSD3B7, STX1B, STX4, AC135050.3, AC135050.1, ZNF668, AC135050.4, ZNF646, PRSS53, AC135050.2, VKORC1, AC135050.7, BCKDK, KAT8, AC135050.5, AC135050.6, AC009088.3, PRSS8, PRSS36, AC009088.4, NDUFA3P6, FUS, AC009088.2, AC009088.1, PYCARD, PYCARD-AS1, TRIM72, PYDC1, ITGAM.

Autosomal genes at a single copy (total copy number 1): 7,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
